Somatic mutation profile of tumor specimen TCGA-66-2759-01A (aliquot TCGA-66-2759-01A-01W-0877-08) from TCGA case TCGA-66-2759, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.5 years (24,287 days).
Specimen TCGA-66-2759-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6547193d-f532-4f91-b798-16ba6acbac3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2759-11A (Solid Tissue Normal), aliquot TCGA-66-2759-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/913f0932-38ca-479f-9365-7caf3082eeb1

The open-access MAF lists 439 somatic variants for this specimen: 330 protein-altering or splice-affecting, 96 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 96, Nonsense Mutation 23, Frame Shift Del 9, RNA 7, Splice Region 5, Intron 5, Splice Site 3, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 117/282 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- WNT7A | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514666, CM110768, COSV53196797; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2222G>T p.R741I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as rs1359542599, COSV55944473, COSV55960216; called by muse, mutect2, varscan2
- ABCC12 | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60917089; called by muse, mutect2, varscan2
- ACSM2A | c.1205T>G p.L402R (on ENST00000219054; = p.L323R on NM_001308169.2) | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54588378; called by mutect2, varscan2
- ADAM22 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55986573; called by muse, mutect2, varscan2
- ADAMTS19 | c.2699A>T p.H900L | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50782157; called by muse, mutect2
- ADAT1 | c.784A>T p.K262* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV57188025; called by muse, mutect2
- ADGRV1 | c.12016A>T p.I4006F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67992868; called by muse, varscan2
- AGBL1 | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV66869429; called by muse, mutect2, varscan2
- AGTR1 | c.633T>G p.I211M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62559696; called by muse, mutect2, varscan2
- AHI1 | c.1460A>G p.N487S | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV55633732; called by muse, mutect2, varscan2
- ALDOB | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66398433, COSV99058870; called by muse, mutect2, varscan2
- ALPK2 | c.149A>C p.Q50P | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV64495856; called by muse, mutect2, varscan2
- AMPH | c.1801C>A p.P601T | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV57750139; called by muse, mutect2
- AMY2B | c.1417A>G p.I473V | Missense Mutation (SNP) | VAF 190/1052 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63716611; called by muse, mutect2, varscan2
- ANK2 | c.10046C>T p.P3349L | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100003248, COSV52180948; called by muse, mutect2, varscan2
- ANO2 | c.2444C>A p.A815D (on ENST00000356134 / NM_001278597.3; = p.A819D on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59035831; called by muse, mutect2
- ANP32B | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV59587524; called by muse, mutect2, varscan2
- APBB1 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54979645; called by muse, mutect2, varscan2
- ARMC1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV52534580; called by muse, mutect2, varscan2
- ASAH2 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as COSV61484242; called by muse, mutect2, varscan2
- ASPM | c.8094C>G p.F2698L | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV54136027; called by muse, mutect2, varscan2
- ATAT1 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 86/499 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs760636161, COSV53315730; called by muse, mutect2, varscan2
- ATF7IP | c.3145A>C p.T1049P | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.03); catalogued as rs779593459, COSV53775695; called by muse, mutect2, varscan2
- ATG13 | c.1076G>T p.R359L (on ENST00000359513 / NM_001346321.1; = p.R322L on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV56321446; called by muse, mutect2, varscan2
- ATP10A | c.1265A>T p.Q422L | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV63521854; called by muse, mutect2, varscan2
- ATP6V1A | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56363875; called by muse, mutect2, varscan2
- ATRNL1 | c.1888G>C p.G630R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV61796035, COSV61813253; called by muse, mutect2, varscan2
- ATXN2 | c.2692G>T p.D898Y (on ENST00000550104; = p.D738Y on NM_002973.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV66485449; called by muse, mutect2, varscan2
- B3GALT1 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs746868901, COSV59908017; called by muse, mutect2, varscan2
- BCHE | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV52258770, COSV52260684, COSV52263960; called by muse, mutect2, varscan2
- BIRC6 | c.13588G>T p.A4530S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV70204096; called by muse, mutect2
- C1D | c.380C>A p.S127* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs752414784, COSV63413769; called by muse, mutect2, varscan2
- C6 | c.2242G>C p.G748R | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV54715978, COSV99666481; called by muse, mutect2, varscan2
- CALCR | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426673237, COSV64009835, COSV64011006; called by muse, mutect2, varscan2
- CALHM2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53297436; called by mutect2, varscan2
- CCDC18 | c.3157G>A p.E1053K (on ENST00000343253 / NM_001306076.1; = p.E1054K on NM_206886.4) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV58146546; called by muse, mutect2, varscan2
- CCNJL | c.1114G>C p.G372R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV57446322; called by muse, mutect2, varscan2
- CDH1 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs864622184, COSV55729855, COSV55738645; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52570402, COSV52592855; called by muse, mutect2, varscan2
- CDH2 | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 84/481 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as COSV52292173; called by muse, mutect2, varscan2
- CENPW | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 191/314 reads (61%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV64177153; called by muse, mutect2, varscan2
- CEP89 | c.494T>C p.V165A | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as COSV59866795; called by muse, mutect2, varscan2
- CES5A | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV51869424; called by muse, mutect2, varscan2
- CFAP97 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71712876; called by muse, mutect2, varscan2
- CFL2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs779077709, COSV53311167; called by muse, mutect2, varscan2
- CHRNA9 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1342521367, COSV59573400; called by muse, mutect2, varscan2
- CNKSR2 | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as COSV54263685; called by muse, mutect2, varscan2
- CNTNAP2 | c.1519A>T p.N507Y | Missense Mutation (SNP) | VAF 156/440 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV62237800; called by muse, varscan2
- CNTNAP4 | c.1681G>C p.G561R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV100271916, COSV56695578; called by muse, mutect2, varscan2
- CNTNAP4 | c.2695A>T p.T899S | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV56695589; called by muse, mutect2, varscan2
- COL1A1 | c.1735G>A p.V579M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV56806219; called by muse, mutect2, varscan2
- COL4A1 | c.1700C>A p.P567Q | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV65427806, COSV65430121; called by muse, mutect2, varscan2
- COL8A1 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 46/69 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV53740215; called by muse, mutect2, varscan2
- CPB2 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51676650; called by muse, mutect2, varscan2
- CROT | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 88/572 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV58976276; called by muse, mutect2, varscan2
- CRY1 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV50488434; called by muse, mutect2, varscan2
- CYP2C9 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 167/643 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV53251604; called by muse, mutect2, varscan2
- DBNDD2 | c.302C>G p.P101R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as COSV61919260; called by muse, mutect2, varscan2
- DECR1 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV55170110; called by muse, mutect2, varscan2
- DENND5A | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60236938; called by muse, mutect2, varscan2
- DHRSX | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58137729; called by muse, mutect2, varscan2
- DHX32 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs370623553; called by mutect2, varscan2
- DMBX1 | c.36C>A p.H12Q | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV63602462; called by muse, mutect2, varscan2
- DMD | c.7978C>T p.H2660Y | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs757616080, COSV58940372; called by muse, mutect2, varscan2
- DNAH8 | c.6313C>T p.P2105S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV59471853; called by muse, mutect2, varscan2
- DPP8 | c.1631A>G p.K544R (on ENST00000341861 / NM_001320875.2; = p.K528R on NM_017743.6) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.123); catalogued as COSV55682101; called by muse, mutect2, varscan2
- DPYD | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929217; called by muse, mutect2
- DSC1 | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 144/330 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.287); catalogued as COSV57149875; called by muse, mutect2, varscan2
- EBF1 | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 75/510 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58190481; called by muse, mutect2, varscan2
- EDEM3 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436390075, COSV58927026; called by muse, mutect2, varscan2
- EIF5 | c.153G>T p.T51= | Splice Region (SNP) | VAF 22/32 reads (69%) | catalogued as COSV53686465; called by muse, mutect2, varscan2
- ENOX2 | c.445G>T p.E149* (on ENST00000338144 / NM_001382520.1; = p.E120* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 120/207 reads (58%) | catalogued as COSV100584325, COSV57656535; called by muse, mutect2, varscan2
- ENPEP | c.438G>C p.E146D | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.068); catalogued as COSV54455831; called by muse, mutect2, varscan2
- EPG5 | c.7030G>T p.G2344* | Nonsense Mutation (SNP) | VAF 48/161 reads (30%) | catalogued as COSV56354478; called by muse, mutect2, varscan2
- EPHB2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV65865371; called by mutect2, varscan2
- ERICH3 | c.4424G>A p.R1475Q | Missense Mutation (SNP) | VAF 218/654 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs759558131, COSV58606884, COSV58611028; called by muse, mutect2, varscan2
- ERICH3 | c.479T>C p.M160T | Missense Mutation (SNP) | VAF 144/736 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1417236438, COSV58614924; called by muse, mutect2, varscan2
- FAM90A1 | c.132C>A p.C44* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV56714157; called by muse, mutect2, varscan2
- FASTKD3 | c.134T>C p.L45S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52946103; called by muse, mutect2, varscan2
- FAT2 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV55826977; called by muse, mutect2, varscan2
- FAT3 | c.8167A>C p.I2723L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.555); catalogued as COSV53134254, COSV53158191; called by muse, mutect2
- FBXO9 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55056824; called by muse, mutect2, varscan2
- FGF14 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs1228022005, COSV65953827; called by muse, mutect2, varscan2
- FLG2 | c.2291G>A p.R764K | Missense Mutation (SNP) | VAF 678/1662 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs763201806, COSV66171739; called by mutect2, varscan2
- FXR1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 83/635 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV59765588; called by muse, mutect2, varscan2
- GABRB2 | c.528G>T p.L176F | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50933305; called by muse, mutect2, varscan2
- GALNT13 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV101222170, COSV67233749; called by muse, mutect2, varscan2
- GALNT17 | c.1758C>A p.C586* | Nonsense Mutation (SNP) | VAF 19/117 reads (16%) | catalogued as COSV61183053; called by muse, mutect2, varscan2
- GFRAL | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 123/582 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61234160; called by muse, mutect2, varscan2
- GLIPR1L1 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1241605702, COSV56883363; called by muse, mutect2, varscan2
- GOLT1B | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57554025; called by muse, mutect2, varscan2
- GP5 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.386); catalogued as COSV55468440, COSV99757188; called by muse, varscan2
- GPR87 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 62/770 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs531293531, COSV53464157; called by muse, mutect2
- GRIA3 | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52075945; called by muse, mutect2, varscan2
- GRIA3 | c.1223T>A p.F408Y | Missense Mutation (SNP) | VAF 434/674 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV52075977; called by muse, mutect2, varscan2
- GRIA3 | c.1901G>C p.G634A | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52076006; called by muse, mutect2, varscan2
- GRID1 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV60046448; called by muse, mutect2, varscan2
- GRIK2 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV59760879; called by muse, mutect2, varscan2
- GRPR | c.1138C>A p.H380N | Missense Mutation (SNP) | VAF 197/349 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.204); catalogued as COSV66670076; called by muse, mutect2, varscan2
- H2AC17 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV58153657; called by muse, mutect2, varscan2
- H2BC17 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.686); catalogued as COSV100377708, COSV58152797; called by muse, mutect2, varscan2
- HDAC9 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV67771105; called by muse, mutect2, varscan2
- HECW2 | c.2185G>T p.D729Y | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.259); catalogued as COSV53664965, COSV53670518; called by muse, mutect2, varscan2
- HHIPL2 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147794680; called by muse, mutect2
- HNRNPC | c.790G>T p.G264W (on ENST00000420743; = p.G251W on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60146733; called by muse, mutect2, varscan2
- HRH4 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 63/127 reads (50%) | catalogued as COSV56927364, COSV56929370; called by muse, mutect2, varscan2
- HROB | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372363245, COSV55370390; called by muse, mutect2, varscan2
- HUS1B | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100032947, COSV57870288; called by muse, mutect2, varscan2
- IBSP | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV56896863; called by muse, mutect2, varscan2
- IGSF8 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58758944; called by muse, mutect2, varscan2
- IL1RL1 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 253/515 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119459; called by muse, mutect2, varscan2
- IL23R | c.1442A>C p.N481T | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.178); catalogued as COSV61375756; called by muse, mutect2, varscan2
- INO80 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV62741579; called by muse, varscan2
- ITGA2 | c.323A>T p.E108V | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56865073; called by muse, mutect2, varscan2
- ITGA5 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53220005; called by muse, mutect2, varscan2
- JAGN1 | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.255); catalogued as COSV57062734; called by muse, mutect2, varscan2
- KCNH7 | c.2078C>G p.P693R | Missense Mutation (SNP) | VAF 107/797 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59785044, COSV59809040; called by muse, mutect2, varscan2
- KCNJ3 | c.861C>A p.S287R | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV54542210; called by muse, mutect2, varscan2
- KCNQ3 | c.2614A>C p.I872L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV66478967; called by muse, mutect2, varscan2
- KCNQ3 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV66478975; called by muse, mutect2, varscan2
- KCTD8 | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV63588502, COSV63594237; called by muse, mutect2, varscan2
- KDM4D | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58635901; called by muse, mutect2, varscan2
- KIF2B | c.1522A>G p.I508V | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV52134256; called by muse, mutect2, varscan2
- KIF9 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55522654; called by muse, mutect2, varscan2
- KLF9 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV65808040; called by muse, mutect2, varscan2
- KLHL34 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65280104; called by muse, mutect2, varscan2
- KLK3 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 98/207 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58102218; called by muse, mutect2, varscan2
- KMT2A | c.11167C>G p.L3723V | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.047); catalogued as COSV63290739, COSV63293807; called by muse, mutect2, varscan2
- KRT16 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV56969254; called by muse, mutect2, varscan2
- KYNU | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51589513; called by muse, mutect2
- LEPR | c.3058T>A p.L1020M | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.553); catalogued as COSV62750776; called by muse, mutect2, varscan2
- LIFR | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 141/602 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773256377, COSV54688433, COSV54693340; called by muse, mutect2, varscan2
- LNPK | c.1060T>G p.L354V | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55825779; called by muse, mutect2
- LONP2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53524925; called by muse, mutect2, varscan2
- LPP | c.1541T>G p.F514C | Missense Mutation (SNP) | VAF 78/475 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756943851, COSV57108772; called by muse, mutect2, varscan2
- LRP2 | c.11809A>G p.N3937D | Missense Mutation (SNP) | VAF 147/264 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV55568165; called by muse, mutect2, varscan2
- LRRFIP1 | c.517A>T p.K173* (on ENST00000392000 / NM_001137552.2; = p.K149* on NM_004735.4) | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV55255207; called by muse, mutect2, varscan2
- LRRTM1 | c.1041C>A p.Y347* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV54445311, COSV54447246; called by muse, mutect2
- LRRTM1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as rs762370564, COSV54440772; called by muse, mutect2, varscan2
- M1AP | c.1142C>G p.A381G | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV51847409; called by muse, mutect2, varscan2
- MAPKAPK5 | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV72431654; called by muse, varscan2
- MCCC1 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV55611065; called by muse, mutect2
- MCF2L2 | c.1874G>T p.R625L | Missense Mutation (SNP) | VAF 30/307 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV61054597, COSV61059344; called by muse, mutect2, varscan2
- MED18 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 81/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65790900, COSV65791025; called by muse, mutect2, varscan2
- MKRN1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV55438117; called by muse, mutect2, varscan2
- MPP7 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV61735993, COSV61736578; called by muse, mutect2, varscan2
- MSANTD2 | c.1352G>T p.R451L (on ENST00000374979 / NM_001308027.2; = p.R399L on NM_024631.4) | Missense Mutation (SNP) | VAF 159/296 reads (54%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV53450473; called by muse, mutect2, varscan2
- MTERF4 | c.883A>T p.R295* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as COSV54090559; called by muse, mutect2, varscan2
- MUC16 | c.40619A>T p.K13540M | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66695561; called by muse, mutect2, varscan2
- MYH2 | c.5371A>G p.N1791D | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55445671; called by muse, mutect2, varscan2
- MYH4 | c.5344C>T p.H1782Y | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55124004; called by muse, mutect2, varscan2
- NAALAD2 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 15/116 reads (13%) | catalogued as COSV58959808, COSV58964692; called by muse, mutect2, varscan2
- NALCN | c.2316C>G p.N772K | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV51956835; called by muse, mutect2, varscan2
- NALCN | c.1574T>C p.L525S | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51956844; called by muse, mutect2
- NCOA6 | c.5588G>T p.G1863V | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.127); catalogued as COSV62866749; called by muse, mutect2, varscan2
- NDC1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV52338050; called by muse, mutect2, varscan2
- NDST4 | c.2578C>A p.L860M | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV52132260; called by muse, mutect2, varscan2
- NEK5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62881389; called by muse, mutect2, varscan2
- NLGN4Y | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV59298918; called by muse, mutect2, varscan2
- NME8 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 195/631 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV52254274; called by muse, mutect2, varscan2
- NOD2 | c.1358A>G p.E453G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV56053885; called by muse, varscan2
- NPAP1 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.791); catalogued as COSV61510142, COSV61512194; called by muse, mutect2, varscan2
- NRK | c.2570C>G p.P857R | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as COSV54603676; called by muse, mutect2, varscan2
- NSD3 | c.3928C>T p.R1310* | Nonsense Mutation (SNP) | VAF 16/329 reads (5%) | catalogued as COSV104395134, COSV57666971; called by muse, mutect2
- NT5C2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV58418569; called by muse, mutect2, varscan2
- NXPE4 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 427/872 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as COSV64944250; called by muse, mutect2, varscan2
- OAS3 | c.805T>A p.W269R | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57448236; called by muse, mutect2, varscan2
- OR2D2 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV55057988; called by muse, mutect2, varscan2
- OR2G6 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 61/591 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58574384; called by muse, mutect2, varscan2
- OR4C6 | c.171G>C p.M57I | Missense Mutation (SNP) | VAF 86/352 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV58602424, COSV58605756; called by muse, mutect2, varscan2
- OR52J3 | c.764del p.P255Lfs*28 | Frame Shift Del (DEL) | VAF 80/473 reads (17%) | catalogued as COSV66746680, COSV66747476; called by mutect2, pindel, varscan2
- OR5D18 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV100450843, COSV61738281; called by muse, mutect2, varscan2
- OR5H14 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 190/928 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101454215, COSV71194398; called by muse, mutect2, varscan2
- OR5M11 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV73141656, COSV73141975; called by muse, mutect2, varscan2
- OR5T2 | c.417G>T p.Q139H | Missense Mutation (SNP) | VAF 66/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1187096923, COSV57590534, COSV57591510; called by muse, mutect2, varscan2
- OR5W2 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as COSV60617857; called by muse, mutect2, varscan2
- OR6Y1 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 389/661 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV56930984; called by muse, mutect2, varscan2
- OR8B4 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs1402100050, COSV62070339; called by muse, mutect2, varscan2
- OR8D4 | c.29C>A p.T10N | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV58431170; called by muse, mutect2, varscan2
- OR8D4 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754468576, COSV58431181, COSV58431755; called by muse, varscan2
- P4HA2 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.366); catalogued as COSV51329915; called by muse, mutect2, varscan2
- PAK5 | c.1664C>A p.A555D | Missense Mutation (SNP) | VAF 101/191 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62035027; called by muse, mutect2, varscan2
- PANX3 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52513441; called by muse, mutect2
- PAPSS2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs755679218, COSV63264694; called by muse, mutect2, varscan2
- PARPBP | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs750737952, COSV59675851; called by muse, mutect2, varscan2
- PC | c.2144G>A p.R715H | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs758589916, COSV58993727; called by muse, mutect2, varscan2
- PCCA | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV66197163, COSV66200004; called by muse, mutect2, varscan2
- PCDH15 | c.2156C>A p.P719H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV57360844, COSV57371559; called by muse, mutect2, varscan2
- PCDHB12 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs532396499, COSV53398691, COSV99507128; called by muse, mutect2, varscan2
- PCDHGA3 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV54007596; called by muse, mutect2, varscan2
- PDS5A | c.2192G>C p.G731A | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57829508; called by muse, mutect2
- PDZD4 | c.486+1G>T p.X162_splice | Splice Site (SNP) | VAF 7/11 reads (64%) | catalogued as rs1557077167, COSV51246866, COSV51249698; called by muse, mutect2, varscan2
- PHF20L1 | c.2639G>C p.G880A | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55196627; called by muse, mutect2
- PIGN | c.2000T>C p.V667A | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs747013434, COSV62951233; called by muse, mutect2, varscan2
- PIKFYVE | c.3521A>G p.K1174R | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.15); catalogued as COSV52237869, COSV52247032; called by muse, mutect2, varscan2
- PKHD1L1 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as rs866893811, COSV65750112; called by muse, mutect2, varscan2
- PLCH1 | c.3628G>A p.A1210T (on ENST00000340059 / NM_001130960.2; = p.A1202T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs887061354, COSV58207488; called by muse, mutect2, varscan2
- PNLIPRP3 | c.685+2T>A p.X229_splice | Splice Site (SNP) | VAF 22/83 reads (27%) | catalogued as COSV65049315; called by muse, mutect2, varscan2
- PNPLA4 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV66854406; called by muse, mutect2, varscan2
- PORCN | c.170T>A p.V57E | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV58226974; called by muse, mutect2, varscan2
- POTEH | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV58885822; called by muse, mutect2, varscan2
- POU4F3 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs1449371669, COSV57944627; called by muse, mutect2, varscan2
- PPCS | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.071); catalogued as COSV65333844; called by muse, mutect2, varscan2
- PPIL6 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 94/121 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57806619; called by muse, mutect2, varscan2
- PPP4R1 | c.2221C>G p.L741V (on ENST00000400556 / NM_001042388.3; = p.L724V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53283877; called by muse, mutect2, varscan2
- PPP4R4 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 96/167 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV58557239; called by muse, mutect2, varscan2
- PTGDR | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.198); catalogued as COSV60094767; called by muse, mutect2, varscan2
- PTGS2 | c.1406-1G>C p.X469_splice | Splice Site (SNP) | VAF 130/178 reads (73%) | catalogued as COSV100821735; called by muse, mutect2, varscan2
- R3HDML | c.342G>C p.M114I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV53837362; called by muse, mutect2, varscan2
- RAG2 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as CM114604, COSV57559138; called by muse, mutect2, varscan2
- RASD2 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs368099253; called by muse, mutect2, varscan2
- RBM8A | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 207/340 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV57162852; called by muse, mutect2, varscan2
- REC114 | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV58524193; called by muse, mutect2, varscan2
- REC8 | c.417G>T p.M139I | Missense Mutation (SNP) | VAF 99/253 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV61017928; called by muse, mutect2, varscan2
- REG1B | c.186C>A p.L62= | Splice Region (SNP) | VAF 55/270 reads (20%) | catalogued as COSV59304209, COSV59307286; called by muse, mutect2, varscan2
- RFPL3 | c.460C>T p.Q154* (on ENST00000249007 / NM_001098535.1; = p.Q125* on NM_006604.2) | Nonsense Mutation (SNP) | VAF 50/199 reads (25%) | catalogued as COSV50751875; called by muse, mutect2, varscan2
- RFX6 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.079); catalogued as COSV60585131; called by muse, mutect2, varscan2
- RIMS2 | c.521A>C p.E174A | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.824); catalogued as COSV68113280; called by muse, mutect2, varscan2
- RLF | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV65652815; called by muse, mutect2, varscan2
- RNASE3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.264); catalogued as rs1372547752, COSV58959761, COSV58959881; called by muse, mutect2, varscan2
- RNF148 | c.399A>T p.Q133H | Missense Mutation (SNP) | VAF 352/906 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV57379856; called by muse, mutect2, varscan2
- RNF186 | c.261G>C p.K87N | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV64296909; called by muse, mutect2, varscan2
- RP1 | c.2967G>T p.E989D | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV55123921; called by muse, mutect2, varscan2
- RPS4Y2 | c.462C>G p.I154M | Missense Mutation (SNP) | VAF 545/844 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56488806; called by muse, mutect2, varscan2
- RTL10 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV60736199; called by mutect2, varscan2
- RTN2 | c.1145A>G p.H382R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1299941264; called by muse, mutect2, varscan2
- RTP2 | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 76/417 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV64079348; called by muse, mutect2, varscan2
- RXFP1 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV57054678; called by muse, mutect2, varscan2
- RYR2 | c.6022G>T p.G2008* | Nonsense Mutation (SNP) | VAF 46/73 reads (63%) | catalogued as COSV63705838, COSV63724133; called by muse, mutect2, varscan2
- RYR3 | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs575120914, COSV101212122, COSV66777575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.4474G>C p.E1492Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV66535403, COSV66545358; called by muse, mutect2, varscan2
- SAMD12 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59055123; called by muse, mutect2
- SBSPON | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52077584; called by muse, mutect2, varscan2
- SDK1 | c.3055C>T p.L1019F | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as rs759882865, COSV67360341, COSV67383912; called by muse, mutect2, varscan2
- SEMA3G | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51597681; called by muse, mutect2, varscan2
- SESN1 | c.496G>A p.E166K (on ENST00000356644 / NM_001199933.1; = p.E225K on NM_014454.3) | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1032022376, COSV57421660; called by muse, mutect2, varscan2
- SIM1 | c.1740C>A p.N580K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV53495363; called by muse, varscan2
- SLC19A2 | c.1214C>A p.T405K | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52548667; called by muse, mutect2, varscan2
- SLIT2 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56589359; called by muse, mutect2
- SLITRK3 | c.2210G>T p.G737V | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV53852188; called by muse, mutect2, varscan2
- SLITRK3 | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs894110841, COSV53852200, COSV99072036; called by muse, mutect2, varscan2
- SORCS1 | c.598G>T p.G200W | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53839738; called by muse, mutect2, varscan2
- SPIC | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV54692238, COSV54692405; called by muse, mutect2, varscan2
- STAB2 | c.2442C>A p.C814* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | catalogued as COSV66344717; called by muse, mutect2, varscan2
- STARD6 | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV57143231; called by muse, mutect2, varscan2
- STK31 | c.203T>A p.V68D | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63458646; called by muse, mutect2, varscan2
- SWI5 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 44/180 reads (24%) | catalogued as COSV60792878; called by muse, mutect2, varscan2
- TAX1BP1 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs775012539, COSV55295936; called by muse, mutect2, varscan2
- TENT5D | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 64/100 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100382689, COSV57638597; called by muse, mutect2, varscan2
- TEX55 | c.466A>G p.R156G | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.37); catalogued as COSV55212475; called by muse, mutect2, varscan2
- TFAM | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.439); catalogued as COSV65876227, COSV65877031; called by muse, mutect2, varscan2
- TGM7 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 63/319 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV71773051; called by muse, mutect2, varscan2
- THAP12 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as COSV52612210; called by muse, mutect2, varscan2
- TINAGL1 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 90/206 reads (44%) | catalogued as rs1436224085, COSV54699748; called by muse, mutect2, varscan2
- TLL2 | c.2952G>A p.M984I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV63574933; called by muse, mutect2, varscan2
- TLN2 | c.2634G>C p.K878N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60894021; called by muse, mutect2, varscan2
- TMC1 | c.1698T>C p.P566= | Splice Region (SNP) | VAF 78/274 reads (28%) | catalogued as COSV52782851; called by muse, mutect2, varscan2
- TNK2 | c.1164C>T p.A388= | Splice Region (SNP) | VAF 29/113 reads (26%) | catalogued as COSV57374264; called by muse, mutect2, varscan2
- TNXB | c.9166G>T p.E3056* (on ENST00000647633; = p.E2809* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV64477366, COSV64486489, COSV64487656; called by muse, varscan2
- TPO | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755919271, COSV61108700; called by muse, mutect2, varscan2
- TRIM32 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs773872830, COSV57765458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM37 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1205021212, COSV51887531; called by muse, mutect2, varscan2
- TRIM51 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV55269714; called by muse, mutect2, varscan2
- TRPM6 | c.4476G>C p.K1492N | Missense Mutation (SNP) | VAF 116/433 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100667093, COSV62519814; called by muse, mutect2, varscan2
- TSPAN11 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs774396624, COSV53820715; called by muse, mutect2, varscan2
- TSPAN9 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs1435673633, COSV50727004; called by muse, mutect2, varscan2
- TTC17 | c.1199T>C p.M400T | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs750635072, COSV50015419; called by muse, mutect2, varscan2
- TTN | c.14209T>C p.C4737R (on ENST00000591111; = p.C3810R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/331 reads (40%) | PolyPhen probably damaging (0.998); catalogued as COSV60200307, COSV60265091; called by muse, mutect2, varscan2
- TTN | c.8630T>G p.L2877R (on ENST00000591111; = p.L2831R on NM_003319.4) | Missense Mutation (SNP) | VAF 106/199 reads (53%) | PolyPhen probably damaging (0.97); catalogued as COSV60265104; called by muse, mutect2, varscan2
- UBE2R2 | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 205/356 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54292068; called by muse, mutect2, varscan2
- UBQLN3 | c.1531C>T p.L511F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV61165187; called by muse, mutect2, varscan2
- UGT3A1 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV57101689; called by muse, mutect2, varscan2
- UNC79 | c.5045C>A p.A1682D (on ENST00000393151 / NM_001346218.2; = p.A1505D on NM_020818.5) | Missense Mutation (SNP) | VAF 145/287 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV56404493; called by muse, mutect2, varscan2
- URGCP | c.659C>T p.S220L (on ENST00000453200 / NM_001077663.3; = p.S211L on NM_017920.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.349); catalogued as rs776969467, COSV56250145, COSV56251401; called by muse, mutect2, varscan2
- USH2A | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.237); catalogued as COSV56416906; called by muse, mutect2, varscan2
- USP28 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 140/844 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as COSV50179086, COSV99134399; called by muse, varscan2
- VPS50 | c.2208G>A p.L736= | Splice Region (SNP) | VAF 24/126 reads (19%) | catalogued as COSV100004694, COSV59921889; called by muse, mutect2, varscan2
- VPS50 | c.2513G>T p.R838L | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.988); catalogued as COSV59921893; called by muse, mutect2, varscan2
- VWA5A | c.1832C>A p.P611Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV64414038; called by muse, mutect2, varscan2
- WDFY3 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 45/126 reads (36%) | catalogued as COSV55710905; called by muse, mutect2, varscan2
- WDR35 | c.2802A>G p.I934M (on ENST00000345530 / NM_001006657.2; = p.I923M on NM_020779.4) | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV55605828; called by muse, mutect2, varscan2
- WDR49 | c.1119G>T p.M373I (on ENST00000308378 / NM_001366158.1; = p.M714I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV57715328; called by muse, mutect2, varscan2
- WFIKKN2 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV60959866; called by muse, mutect2, varscan2
- WNK1 | c.3601G>C p.E1201Q (on ENST00000315939 / NM_018979.4; = p.E954Q on NM_014823.3) | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60042553; called by muse, mutect2, varscan2
- WNT2 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV55412973; called by mutect2, varscan2
- XIRP2 | c.7519T>G p.C2507G (on ENST00000628543; = p.C2682G on NM_152381.6) | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV54725554; called by muse, mutect2
- ZC3H12A | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV66104452; called by muse, mutect2, varscan2
- ZDHHC17 | c.1091T>C p.L364S | Missense Mutation (SNP) | VAF 195/913 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58353598; called by muse, mutect2, varscan2
- ZFHX3 | c.10360G>T p.D3454Y | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs770453754, COSV51709324, COSV51730529; called by muse, mutect2, varscan2
- ZFHX4 | c.4886G>T p.S1629I | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV51487287; called by muse, mutect2, varscan2
- ZFHX4 | c.8506G>T p.A2836S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as rs754367335, COSV51487306; called by muse, mutect2, varscan2
- ZFR | c.2020G>C p.E674Q | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV54053334, COSV54056731; called by muse, mutect2, varscan2
- ZIC4 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as COSV67173534; called by muse, mutect2, varscan2
- ZKSCAN2 | c.947T>A p.V316D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV60158282; called by muse, mutect2, varscan2
- ZNF146 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | catalogued as COSV61932457; called by muse, mutect2, varscan2
- ZNF205 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs753094902, COSV54622478; called by muse, varscan2
- ZNF23 | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as COSV61841538; called by muse, mutect2, varscan2
- ZNF236 | c.2363A>T p.Q788L | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV53494900; called by muse, mutect2, varscan2
- ZNF462 | c.343C>A p.R115S | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52948255; called by muse, mutect2, varscan2
- ZNF521 | c.3419G>T p.C1140F | Missense Mutation (SNP) | VAF 88/293 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64130601; called by muse, mutect2, varscan2
- ZNF804A | c.1186C>A p.P396T | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV56465187; called by muse, mutect2, varscan2
- ZNF91 | c.2879A>G p.H960R | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56090438; called by muse, mutect2, varscan2
- ZNF91 | c.858G>T p.R286S | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV56090463; called by muse, mutect2, varscan2
- ZSWIM2 | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV54578222; called by muse, mutect2, varscan2
- ABCC1 | c.2153_2162del p.Q718Lfs*20 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | called by mutect2, pindel, varscan2
- ADCY9 | c.1117del p.S373Lfs*8 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- ADGRG6 | c.3381_3383del p.Q1127del | In Frame Del (DEL) | VAF 99/220 reads (45%) | called by pindel, varscan2
- CCDC14 | c.1475C>A p.S492* (on ENST00000488653; = p.S444* on NM_022757.5) | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- CMYA5 | c.7820C>T p.P2607L | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- COL19A1 | c.3415A>G p.T1139A | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); called by muse, mutect2
- CS | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- FKBP15 | c.3398del p.G1133Vfs*45 | Frame Shift Del (DEL) | VAF 29/97 reads (30%) | called by mutect2, pindel, varscan2
- GAL3ST1 | c.206C>A p.A69E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by mutect2, varscan2
- GOLGA3 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- H2AC15 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IGHV3-15 | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MCHR2 | c.772del p.V258* | Frame Shift Del (DEL) | VAF 101/855 reads (12%) | called by mutect2, pindel, varscan2
- NUDT21 | c.683G>T p.*228Lext*15 | Nonstop Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, varscan2
- PPHLN1 | c.1115_1116insA p.A373Cfs*49 | Frame Shift Ins (INS) | VAF 70/269 reads (26%) | called by mutect2, pindel, varscan2
- PTPN21 | c.3464G>C p.C1155S | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- PTPN4 | c.1903del p.D635Mfs*9 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel, varscan2
- SALL1 | c.261del p.S88Afs*11 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | called by mutect2, pindel, varscan2
- SLC7A6 | c.1365C>G p.I455M | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- TDRD9 | c.4084G>C p.E1362Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- USP19 | c.1558del p.E520Nfs*21 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- USP9X | c.5685dup p.R1896Sfs*4 | Frame Shift Ins (INS) | VAF 29/72 reads (40%) | called by mutect2, pindel, varscan2
- ZNF598 | c.1285del p.V429Cfs*88 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel
- AADACL3 | c.888G>A p.E296= | Silent (SNP) | VAF 67/380 reads (18%) | catalogued as COSV60200080; called by muse, mutect2, varscan2
- ABCA4 | c.6420G>T p.L2140= | Silent (SNP) | VAF 106/430 reads (25%) | catalogued as COSV64676587; called by muse, mutect2, varscan2
- ANO7 | c.33C>G p.L11= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV51477140, COSV99239303; called by muse, mutect2, varscan2
- ATP10A | c.3258C>A p.A1086= | Silent (SNP) | VAF 84/234 reads (36%) | catalogued as COSV63521849; called by muse, varscan2
- ATP1A2 | c.354C>T p.A118= | Silent (SNP) | VAF 252/371 reads (68%) | catalogued as rs765171580, COSV63405377; ClinVar: likely benign; called by muse, mutect2, varscan2
- C2orf78 | c.2080C>T p.L694= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV68518880; called by muse, mutect2, varscan2
- C7orf57 | c.333G>A p.P111= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as rs758724934, COSV62363759; called by muse, mutect2, varscan2
- CDH17 | c.444C>T p.V148= | Silent (SNP) | VAF 60/233 reads (26%) | catalogued as COSV50336697; called by muse, mutect2, varscan2
- CDH22 | c.336C>A p.I112= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs766868600, COSV64837425, COSV64839145; called by muse, mutect2, varscan2
- CHRND | c.42G>A p.L14= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs746207666, COSV51327444; called by muse, mutect2, varscan2
- CNTN4 | c.2835A>G p.Q945= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs1450816141, COSV61878620; called by muse, mutect2, varscan2
- COL7A1 | c.8292G>A p.E2764= | Silent (SNP) | VAF 81/149 reads (54%) | catalogued as COSV56477061; called by muse, mutect2, varscan2
- CSMD3 | c.7957C>A p.R2653= (on ENST00000297405 / NM_001363185.1; = p.R2549= on NM_052900.3) | Silent (SNP) | VAF 53/141 reads (38%) | catalogued as COSV52140719, COSV52280497; called by muse, mutect2, varscan2
- CTSE | c.1047C>T p.F349= (on ENST00000360218; = p.F344= on NM_001910.4) | Silent (SNP) | VAF 518/840 reads (62%) | catalogued as rs782007406, COSV63061414; called by muse, mutect2, varscan2
- DAPP1 | c.429G>C p.R143= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV56453059; called by muse, mutect2, varscan2
- DDX43 | c.12C>T p.H4= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs768641284, COSV64837693; called by muse, mutect2, varscan2
- DIDO1 | c.1791G>A p.R597= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs140512956; called by muse, mutect2, varscan2
- DNAH8 | c.11370G>A p.L3790= | Silent (SNP) | VAF 80/196 reads (41%) | catalogued as COSV59471871; called by muse, mutect2, varscan2
- ECI2 | c.304C>T p.L102= (on ENST00000380118 / NM_206836.3; = p.L72= on NM_006117.2) | Silent (SNP) | VAF 69/284 reads (24%) | catalogued as COSV60987419; called by muse, mutect2, varscan2
- FANCE | c.330G>T p.P110= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV57690825; called by muse, mutect2, varscan2
- FCGBP | c.735G>A p.T245= | Silent (SNP) | VAF 54/465 reads (12%) | catalogued as rs142265008; called by muse, mutect2, varscan2
- FETUB | c.75C>A p.A25= | Silent (SNP) | VAF 1117/1987 reads (56%) | catalogued as COSV54006416, COSV54006868; called by muse, mutect2, varscan2
- FRMD4B | c.39G>T p.L13= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV68332608; called by muse, varscan2
- GABBR1 | c.2751G>A p.Q917= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100589662; called by muse, mutect2, varscan2
- GALNT1 | c.1191G>A p.S397= | Silent (SNP) | VAF 47/354 reads (13%) | catalogued as rs370655972, COSV99322577; called by muse, mutect2, varscan2
- GLIPR1L2 | c.258G>A p.R86= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV57555423; called by muse, mutect2, varscan2
- GMPR | c.714T>C p.F238= | Silent (SNP) | VAF 170/461 reads (37%) | catalogued as COSV52474823; called by muse, varscan2
- GP5 | c.579G>A p.Q193= | Silent (SNP) | VAF 47/252 reads (19%) | catalogued as rs200544767, COSV55468434; called by muse, varscan2
- GREB1 | c.3654G>A p.S1218= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs370883365; called by muse, mutect2
- GSTCD | c.903C>A p.I301= (on ENST00000360505 / NM_001031720.3; = p.I214= on NM_024751.3) | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV64735081; called by muse, mutect2, varscan2
- HDLBP | c.1338C>T p.F446= | Silent (SNP) | VAF 58/240 reads (24%) | catalogued as COSV60499653; called by muse, mutect2, varscan2
- HECW1 | c.249C>A p.V83= | Silent (SNP) | VAF 66/182 reads (36%) | catalogued as COSV67833430; called by muse, mutect2, varscan2
- HTR3B | c.945C>G p.L315= | Silent (SNP) | VAF 90/509 reads (18%) | catalogued as COSV52746886; called by muse, mutect2, varscan2
- ICE1 | c.3126A>G p.P1042= | Silent (SNP) | VAF 89/364 reads (24%) | catalogued as COSV56830220; called by muse, mutect2, varscan2
- IGHM | c.345C>A p.V115= | Silent (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- ITPR3 | c.2463G>T p.A821= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV65413613; called by muse, mutect2, varscan2
- KCNA5 | c.558G>A p.R186= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs778119687, COSV52907929; called by muse, mutect2, varscan2
- KIF15 | c.966C>T p.F322= | Silent (SNP) | VAF 109/286 reads (38%) | catalogued as rs539059165, COSV58163974; called by muse, mutect2, varscan2
- KIT | c.1680T>A p.V560= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV55415707, COSV55431522; called by muse, mutect2, varscan2
- LEPR | c.909G>T p.S303= | Silent (SNP) | VAF 83/222 reads (37%) | catalogued as COSV100756322, COSV60761364; called by muse, mutect2, varscan2
- LIN7A | c.555G>T p.V185= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as COSV54025996; called by muse, mutect2, varscan2
- LRP2 | c.6849C>T p.I2283= | Silent (SNP) | VAF 107/267 reads (40%) | catalogued as rs1273204726, COSV55568177; called by muse, mutect2, varscan2
- LRRC57 | c.474C>G p.L158= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV53000917, COSV53001557; called by muse, mutect2, varscan2
- LRRTM1 | c.1485C>T p.N495= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV54445296; called by muse, mutect2, varscan2
- MARCHF6 | c.465T>C p.C155= | Silent (SNP) | VAF 79/672 reads (12%) | catalogued as COSV56885699; called by muse, mutect2, varscan2
- MASP1 | c.285C>A p.T95= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV51462746; called by muse, mutect2, varscan2
- MCM2 | c.1314C>T p.V438= | Silent (SNP) | VAF 64/536 reads (12%) | catalogued as COSV54036366; called by muse, mutect2, varscan2
- MVB12A | c.159C>T p.F53= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV57679556; called by muse, mutect2, varscan2
- MYH11 | c.1659G>C p.L553= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV55564901; called by muse, mutect2, varscan2
- NIPA1 | c.753G>A p.A251= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs199718530, COSV61680518; called by mutect2, varscan2
- NLRP11 | c.513C>T p.I171= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV64088478; called by muse, mutect2, varscan2
- NOD1 | c.717C>T p.F239= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV56114181; called by muse, mutect2, varscan2
- NOLC1 | c.1455A>G p.T485= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV64180959; called by muse, mutect2, varscan2
- NRCAM | c.2298G>A p.T766= (on ENST00000379028 / NM_001371124.1; = p.T750= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs759549444, COSV61045817; called by muse, mutect2, varscan2
- NUDT16L1 | c.489C>T p.N163= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs185620630, COSV99274078; called by muse, mutect2, varscan2
- NUDT21 | c.579G>A p.L193= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1349339431; called by muse, varscan2
- OBSCN | c.7983C>T p.R2661= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs747910361, COSV52779958; called by muse, mutect2, varscan2
- OR4A47 | c.483T>C p.I161= | Silent (SNP) | VAF 96/405 reads (24%) | catalogued as rs758478022, COSV71445095; called by muse, mutect2, varscan2
- OR4C46 | c.654C>A p.V218= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs769201663, COSV60220779; called by muse, mutect2, varscan2
- OR8A1 | c.516C>G p.L172= | Silent (SNP) | VAF 66/480 reads (14%) | catalogued as COSV52509644, COSV52510618; called by muse, varscan2
- OR8A1 | c.612C>T p.F204= | Silent (SNP) | VAF 50/296 reads (17%) | catalogued as COSV52509654; called by muse, varscan2
- OR8D4 | c.504C>T p.F168= | Silent (SNP) | VAF 122/427 reads (29%) | catalogued as COSV58431191; called by muse, varscan2
- OR8J3 | c.897T>C p.V299= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV56879338; called by muse, mutect2, varscan2
- OR9K2 | c.678C>T p.S226= (on ENST00000305377; = p.S204= on NM_001005243.1) | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV59533029; called by muse, mutect2, varscan2
- PAK5 | c.2022G>T p.R674= | Silent (SNP) | VAF 183/388 reads (47%) | catalogued as COSV62035020; called by muse, mutect2, varscan2
- PCDHGA4 | c.189C>A p.L63= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV54007607; called by muse, mutect2, varscan2
- PER3 | c.252C>G p.L84= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV50012848; called by muse, mutect2, varscan2
- PHLDB2 | c.1416C>T p.T472= | Silent (SNP) | VAF 156/805 reads (19%) | catalogued as rs112434778; called by muse, mutect2, varscan2
- PIK3R2 | c.2034C>G p.G678= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55849723; called by muse, mutect2, varscan2
- PLBD2 | c.748C>T p.L250= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV55108516; called by muse, mutect2, varscan2
- PRSS21 | c.387C>T p.R129= | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as COSV50052008; called by muse, mutect2, varscan2
- RTL5 | c.1674G>T p.G558= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV65454547; called by muse, mutect2, varscan2
- SCAF4 | c.594C>A p.G198= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV54585452, COSV54590992; called by muse, mutect2, varscan2
- SEC16A | c.5259C>T p.Y1753= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV51537351; called by muse, mutect2, varscan2
- SEMA3B | c.1710G>A p.S570= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs782650950, COSV57114982; called by muse, varscan2
- SENP6 | c.1941C>T p.F647= | Silent (SNP) | VAF 135/241 reads (56%) | catalogued as COSV59193425; called by muse, mutect2, varscan2
- SIDT1 | c.1092C>T p.P364= | Silent (SNP) | VAF 28/176 reads (16%) | catalogued as rs201820793, COSV53505597; called by muse, mutect2, varscan2
- SLCO1B1 | c.1848T>C p.Y616= | Silent (SNP) | VAF 70/202 reads (35%) | catalogued as COSV57015307; called by muse, mutect2, varscan2
- SMG1 | c.9753T>C p.A3251= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1250039557, COSV67174088; called by muse, mutect2
- SPAG16 | c.1503C>A p.T501= | Silent (SNP) | VAF 38/199 reads (19%) | catalogued as COSV59094589; called by muse, mutect2, varscan2
- SPIC | c.147A>T p.G49= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as COSV54692419; called by muse, mutect2, varscan2
- ST8SIA3 | c.27C>A p.V9= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60654978; called by muse, mutect2
- TDRD6 | c.3339G>T p.V1113= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as COSV60177689; called by muse, mutect2, varscan2
- TEX13B | c.333G>A p.L111= | Silent (SNP) | VAF 206/334 reads (62%) | catalogued as COSV57203698; called by muse, mutect2, varscan2
- TMEM268 | c.792C>T p.N264= | Silent (SNP) | VAF 30/229 reads (13%) | catalogued as rs554808792, COSV55987262; called by muse, mutect2, varscan2
- TSPY2 | c.70C>A p.R24= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV57837273; called by mutect2, varscan2
- TTN | c.1251A>G p.K417= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV60265128; called by muse, mutect2, varscan2
- WNK1 | c.5715G>C p.V1905= (on ENST00000315939 / NM_018979.4; = p.V1657= on NM_014823.3) | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV60042574; called by muse, mutect2, varscan2
- XK | c.147G>T p.A49= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV66120694; called by muse, mutect2, varscan2
- ZC3H7B | c.1911C>T p.F637= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs1341216763, COSV60964071; called by muse, mutect2, varscan2
- ZDBF2 | c.219T>A p.T73= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as COSV65629006; called by muse, mutect2, varscan2
- ZFHX4 | c.8505G>T p.P2835= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV50505185, COSV50508878; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1509T>C p.I503= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV66023903; called by muse, mutect2, varscan2
- ZNF169 | c.111C>G p.T37= | Silent (SNP) | VAF 103/333 reads (31%) | catalogued as COSV61765958; called by muse, mutect2, varscan2
- ZNF804B | c.939A>C p.T313= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV60846954; called by muse, mutect2, varscan2
- ZYG11B | c.1821C>T p.A607= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV53755877; called by muse, mutect2, varscan2
- AC005863.1 | n.239A>G | RNA (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- ANK2 | c.84+57117G>T | Intron (SNP) | VAF 8/60 reads (13%) | catalogued as COSV52180938; called by muse, mutect2, varscan2
- BIRC8 | n.1406T>C | RNA (SNP) | VAF 8/193 reads (4%) | called by muse, mutect2
- IGKV1-13 | n.71A>G | RNA (SNP) | VAF 42/176 reads (24%) | catalogued as rs754027263; called by mutect2, varscan2
- LRRC27 | c.926+685G>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs548766487; called by mutect2, varscan2
- MBOAT1 | c.-2G>A | 5'UTR (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100208728; called by muse, mutect2, varscan2
- MIR892A | n.40C>A | RNA (SNP) | VAF 172/326 reads (53%) | called by muse, mutect2, varscan2
- NCOA7 | c.2245-1559A>G | Intron (SNP) | VAF 148/264 reads (56%) | called by muse, mutect2, varscan2
- PDE4A | c.320+9990G>A | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99534047; called by muse, mutect2, varscan2
- SNORD115-20 | n.26G>T | RNA (SNP) | VAF 19/129 reads (15%) | catalogued as rs1284577592; called by muse, mutect2, varscan2
- SPATA8 | n.286C>A | RNA (SNP) | VAF 15/51 reads (29%) | catalogued as COSV60705403; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3362A>G | Intron (SNP) | VAF 102/183 reads (56%) | catalogued as COSV100314110; called by muse, mutect2, varscan2
- UBTFL2 | n.139G>A | RNA (SNP) | VAF 218/405 reads (54%) | called by muse, mutect2, varscan2
